Gene-level copy-number profile of tumor specimen HTMCP-03-06-02204-01B from CGCI case HTMCP-03-06-02204, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1.
Specimen HTMCP-03-06-02204-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4edcd56c-bdf8-4f15-8de7-1bc06df4fbae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02204-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/6336c213-f8b0-4fa2-90ba-16a51765e695

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 9,604; copy number 2: 43,643; copy number 3: 4,241; copy number 4: 328; copy number 5: 477; copy number 6: 54; copy number 7: 3; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,100,340–239,401,654, 30 genes (within-gene range 0–1): ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2, LINC01107, LINC01937, AC113618.2, AC113618.1, AC145625.1, TWIST2, LINC01940, HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–1): PRB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 535 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 4 genes, copy number 5 (within-gene range 2–5): AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr1:212,466,699–212,472,905, 1 gene, copy number 5: LINC02771.
- chr1:246,690,047–246,691,821, 1 gene, copy number 8: AL591848.1.
- chr1:248,906,196–248,937,043, 3 genes, copy number 5: PGBD2, RNU6-1205P, RPL23AP25.
- chr2:197,569–209,892, 1 gene, copy number 6: AC079779.1.
- chr3:11,745–24,849, 1 gene, copy number 5: LINC01986.
- chr5:58,198–189,972, 3 genes, copy number 5–6: AC113430.1, PLEKHG4B, Y_RNA.
- chr5:710,355–2,262,023, 49 genes, copy number 5–7: ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1.
- chr5:16,615,926–16,681,905, 1 gene, copy number 5 (within-gene range 4–5): AC024588.1.
- chr5:16,661,907–45,895,970, 398 genes, copy number 5 (broad region; genes not listed).
- chr5:174,724,582–174,730,896, 1 gene, copy number 5: MSX2.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:145,047,860–145,066,685, 2 genes, copy number 6: AC139103.1, C8orf33.
- chr9:126,860,665–126,885,878, 1 gene, copy number 5: ZBTB34.
- chr11:135,061,781–135,075,908, 1 gene, copy number 5: LINC02684.
- chr13:114,314,482–114,337,626, 2 genes, copy number 7: CHAMP1, LINC01054.
- chr14:22,185,562–22,502,292, 49 genes, copy number 6: TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.

Autosomal genes at a single copy (total copy number 1): 8,162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
